Somatic mutation profile of tumor specimen TCGA-B0-5703-01A (aliquot TCGA-B0-5703-01A-11D-1534-10) from TCGA case TCGA-B0-5703, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 73.6 years (26,897 days).
Specimen TCGA-B0-5703-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 736a9ab3-277b-4720-a985-a9464f98f90f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5703-11A (Solid Tissue Normal), aliquot TCGA-B0-5703-11A-01D-1534-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc97a93b-20fe-4edc-b6cf-1cfb9a0cd7cd

The open-access MAF lists 79 somatic variants for this specimen: 61 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 15, Frame Shift Del 8, Nonsense Mutation 6, Frame Shift Ins 2, 3'UTR 1, Intron 1, 5'UTR 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 155/515 reads (30%) | hotspot (GDC flag); catalogued as rs772821016, CM030188, CS991299, COSV53725394; ClinVar: pathogenic; called by muse, varscan2
- VHL | c.551T>C p.L184P | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064793878, CM042503, CM941389, CM961440, COSV56543194, COSV56543241, COSV56546612; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRA2 | c.889C>T p.L297F | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0.009); catalogued as rs774514376, COSV59446343; called by muse, mutect2, varscan2
- ASAP2 | c.881G>A p.S294N | Missense Mutation (SNP) | VAF 97/330 reads (29%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.968); catalogued as COSV55636781; called by muse, mutect2, varscan2
- ATM | c.2245G>A p.A749T | Missense Mutation (SNP) | VAF 123/377 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.891); catalogued as rs876660163, COSV53765337; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP5 | c.1253G>T p.C418F | Missense Mutation (SNP) | VAF 28/496 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63705454; called by muse, mutect2
- CFAP74 | c.2011A>C p.K671Q | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.539); catalogued as COSV54572150; called by muse, mutect2, varscan2
- CLMN | c.323A>G p.N108S | Missense Mutation (SNP) | VAF 80/235 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.949); catalogued as rs574353507, COSV54186602; called by muse, mutect2, varscan2
- CLPTM1L | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57992089; called by muse, mutect2, varscan2
- CNOT6 | c.755T>C p.V252A | Missense Mutation (SNP) | VAF 140/535 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV56163501; called by muse, mutect2, varscan2
- CNTNAP5 | c.2515C>T p.R839* | Nonsense Mutation (SNP) | VAF 12/371 reads (3%) | catalogued as COSV70474923; called by muse, mutect2
- CRB1 | c.3484C>A p.H1162N | Missense Mutation (SNP) | VAF 98/269 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.253); catalogued as COSV66330475, COSV66330675; called by muse, mutect2, varscan2
- CTSA | c.649T>C p.S217P | Missense Mutation (SNP) | VAF 57/221 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51944133; called by muse, mutect2, varscan2
- DNAH17 | c.13075A>G p.K4359E | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs754530475, COSV53147572; called by muse, mutect2, varscan2
- DNAH3 | c.1289C>G p.S430* | Nonsense Mutation (SNP) | VAF 67/201 reads (33%) | catalogued as COSV54542477; called by muse, mutect2, varscan2
- DOK7 | c.418T>G p.L140V | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV60773370; called by muse, mutect2
- DPP4 | c.342T>G p.I114M | Missense Mutation (SNP) | VAF 110/389 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV62108865; called by muse, mutect2, varscan2
- EXPH5 | c.2591G>T p.C864F | Missense Mutation (SNP) | VAF 39/925 reads (4%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV56206707; called by muse, mutect2
- GMFB | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 177/600 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63737754; called by muse, mutect2, varscan2
- H1-1 | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 148/539 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.115); catalogued as COSV55120311; called by muse, mutect2, varscan2
- KIF1A | c.4154G>A p.W1385* (on ENST00000320389 / NM_001379639.1; = p.W1377* on NM_004321.8 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100239892, COSV57498027; called by muse, mutect2
- KRT34 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.528); catalogued as rs777623549, COSV67450441; called by muse, mutect2
- LTBP4 | c.2990C>T p.A997V (on ENST00000308370 / NM_001042544.1; = p.A960V on NM_003573.2) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.052); catalogued as COSV99189988; called by muse, mutect2
- MAPK14 | c.572C>A p.P191H | Missense Mutation (SNP) | VAF 103/344 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57697309; called by muse, mutect2, varscan2
- MKI67 | c.3982G>A p.G1328S | Missense Mutation (SNP) | VAF 120/246 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs201476882; called by muse, mutect2, varscan2
- MUC16 | c.40471C>G p.R13491G | Missense Mutation (SNP) | VAF 177/659 reads (27%) | SIFT tolerated, low confidence (0.33); PolyPhen probably damaging (0.984); catalogued as COSV66689793, COSV66695495; called by muse, mutect2, varscan2
- MYH2 | c.4163G>A p.R1388H | Missense Mutation (SNP) | VAF 79/225 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs745754711, COSV55432911; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR10J3 | c.185T>C p.F62S | Missense Mutation (SNP) | VAF 20/455 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV59955316; called by muse, mutect2
- PCYOX1 | c.754G>T p.G252C | Missense Mutation (SNP) | VAF 83/350 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52476381, COSV52477786; called by muse, mutect2, varscan2
- PGAP1 | c.569A>C p.K190T | Missense Mutation (SNP) | VAF 81/295 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV61328586; called by muse, mutect2, varscan2
- PLIN4 | c.2985A>T p.K995N (on ENST00000301286; = p.K1010N on NM_001367868.2) | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.889); catalogued as COSV56688636, COSV56696634; called by muse, mutect2, varscan2
- PLXNA4 | c.3476C>T p.T1159M | Missense Mutation (SNP) | VAF 72/310 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as rs774798274, COSV58110834; called by muse, mutect2, varscan2
- PMEPA1 | c.837G>C p.K279N | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV55695622; called by muse, mutect2, varscan2
- PTPRZ1 | c.1135C>G p.L379V | Missense Mutation (SNP) | VAF 112/274 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.377); catalogued as COSV66443133; called by muse, mutect2, varscan2
- RP1 | c.4151T>G p.F1384C | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs557457666, COSV55123765; called by muse, mutect2, varscan2
- RTN4RL1 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs747609277, COSV100486535; called by muse, mutect2, varscan2
- SI | c.2513A>C p.K838T | Missense Mutation (SNP) | VAF 181/534 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV52294060; called by muse, mutect2, varscan2
- SIRPB1 | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 67/196 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.044); catalogued as rs1008776803, COSV53540222; called by muse, mutect2, varscan2
- SIRT1 | c.876T>A p.D292E | Missense Mutation (SNP) | VAF 160/512 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV53019697; called by muse, varscan2
- SIRT1 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 157/510 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53019709; called by muse, varscan2
- SUPT3H | c.814C>G p.Q272E (on ENST00000371460 / NM_181356.3; = p.Q261E on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/326 reads (27%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.465); catalogued as COSV60947192; called by muse, mutect2, varscan2
- SUPT5H | c.2953C>T p.Q985* | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | catalogued as COSV63241430; called by muse, mutect2, varscan2
- TCHH | c.1789A>G p.R597G | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.088); catalogued as COSV64276972; called by muse, mutect2, varscan2
- TENM3 | c.7028A>G p.Y2343C | Missense Mutation (SNP) | VAF 115/361 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1431125753, COSV69315688; called by muse, mutect2, varscan2
- TLE3 | c.865T>A p.S289T | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as COSV58173187; called by muse, mutect2, varscan2
- TOP1 | c.1408A>G p.M470V | Missense Mutation (SNP) | VAF 72/202 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV63695524; called by muse, mutect2, varscan2
- UNC80 | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55883727, COSV55884211; called by muse, mutect2, varscan2
- WDR25 | c.926G>A p.S309N | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs776848385, COSV58939023; called by muse, mutect2, varscan2
- XIRP1 | c.3384del p.R1129Efs*8 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as COSV100453448; called by mutect2, pindel, varscan2
- DNAJC1 | c.759del p.E254Kfs*4 | Frame Shift Del (DEL) | VAF 186/712 reads (26%) | called by mutect2, pindel, varscan2
- FGFR4 | c.1714_1725del p.L572_D575del | In Frame Del (DEL) | VAF 3/15 reads (20%) | called by mutect2, varscan2
- IVL | c.261_273delinsCT p.Q88Lfs*5 | Frame Shift Del (DEL) | VAF 18/69 reads (26%) | called by pindel, varscan2*
- KMT2B | c.4520G>A p.W1507* | Nonsense Mutation (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- MAP3K2 | c.1512del p.S505Afs*14 | Frame Shift Del (DEL) | VAF 63/180 reads (35%) | called by mutect2, pindel, varscan2
- MFAP4 | c.274_275del p.F92Lfs*6 | Frame Shift Del (DEL) | VAF 16/79 reads (20%) | called by mutect2, pindel, varscan2
- NFATC3 | c.1371del p.A458Hfs*9 | Frame Shift Del (DEL) | VAF 55/202 reads (27%) | called by mutect2, pindel, varscan2
- NPAT | c.743dup p.N248Kfs*22 | Frame Shift Ins (INS) | VAF 179/723 reads (25%) | called by mutect2, pindel, varscan2
- PIM3 | c.708dup p.D237Rfs*61 | Frame Shift Ins (INS) | VAF 11/44 reads (25%) | called by mutect2, pindel, varscan2
- SPAG17 | c.3015del p.E1006Sfs*10 | Frame Shift Del (DEL) | VAF 368/1324 reads (28%) | called by mutect2, pindel, varscan2
- TAS2R39 | c.688del p.L230Cfs*2 | Frame Shift Del (DEL) | VAF 68/366 reads (19%) | called by mutect2, pindel, varscan2
- TMC1 | c.65-5_78del p.X22_splice | Splice Site (DEL) | VAF 70/305 reads (23%) | called by mutect2, pindel, varscan2
- AGGF1 | c.1407T>C p.Y469= | Silent (SNP) | VAF 149/507 reads (29%) | catalogued as rs948302676, COSV57230714; called by muse, varscan2
- ALDH3A1 | c.1317G>A p.L439= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV56736432; called by muse, mutect2
- C17orf75 | c.972A>G p.L324= | Silent (SNP) | VAF 126/359 reads (35%) | catalogued as COSV56753870; called by muse, mutect2, varscan2
- CAPZA1 | c.117A>T p.L39= | Silent (SNP) | VAF 30/394 reads (8%) | catalogued as COSV54146698; called by muse, mutect2
- EPB41L4B | c.1359T>C p.P453= | Silent (SNP) | VAF 152/466 reads (33%) | catalogued as COSV65798312; called by muse, mutect2, varscan2
- F5 | c.642A>G p.L214= | Silent (SNP) | VAF 60/205 reads (29%) | catalogued as COSV63126654; called by muse, mutect2, varscan2
- OR5AR1 | c.663C>A p.I221= | Silent (SNP) | VAF 67/249 reads (27%) | catalogued as COSV57254883; called by muse, mutect2, varscan2
- PRAME | c.312T>G p.L104= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV67162307; called by muse, mutect2, varscan2
- PRUNE2 | c.1887C>A p.L629= | Silent (SNP) | VAF 32/346 reads (9%) | catalogued as COSV65045764; called by muse, mutect2
- RGS7 | c.1230C>T p.N410= | Silent (SNP) | VAF 41/405 reads (10%) | catalogued as COSV58535609; called by muse, mutect2, varscan2
- RMND5A | c.498C>T p.V166= | Silent (SNP) | VAF 265/831 reads (32%) | catalogued as COSV52154282; called by muse, mutect2, varscan2
- SLC11A2 | c.555T>A p.A185= (on ENST00000394904 / NM_001379455.1; = p.A156= on NM_000617.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/236 reads (4%) | catalogued as COSV50374567; called by muse, mutect2
- TGFBI | c.381G>A p.K127= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs759397924, COSV59353233; called by muse, mutect2, varscan2
- TGFBI | c.382C>T p.L128= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV59353247; called by muse, mutect2, varscan2
- UNC45B | c.327G>A p.R109= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV52093147; called by muse, mutect2, varscan2
- PFN2 | c.*269C>T | 3'UTR (SNP) | VAF 252/394 reads (64%) | catalogued as COSV99525980; called by muse, mutect2, varscan2
- SLIT2 | c.1463-578C>T | Intron (SNP) | VAF 101/339 reads (30%) | catalogued as rs1261393936, COSV56588435; called by muse, mutect2, varscan2
- SREK1 | c.-23C>G | 5'UTR (SNP) | VAF 89/296 reads (30%) | catalogued as COSV52334609; called by muse, mutect2, varscan2
